Surgical pathology report (de-identified scan), TCGA case TCGA-56-8304, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8304-01A (Primary Tumor).

[page 1 of 3]
SURGERY CASE #: [REDACTED] FINAL

DATE OF SURGERY: [REDACTED]

SURGEON: [REDACTED]

MD

SPECIMEN:
lymph node, lower.

- A. Right upper lobe para bronchial
- B. Right paratracheal lymph node.
- C. Right upper lobe para bronchial
- lymph node.
- D. Right upper lobe
- E. Subcarinal lymph node.

FROZEN SECTION DIAGNOSIS:
tumor. [REDACTED]

- D. Bronchial surgical margins free of

OPERATIVE PROCEDURE:

Right thoracotomy.

PREOPERATIVE DIAGNOSIS:

Right lung mass.

POSTOPERATIVE DIAGNOSIS:

Deferred

COMMENTS:

Squamous cell carcinoma per
previous biopsy, check bronchial margins.

*****DIAGNOSIS*****

A-E.

1. Type of specimen:
Right upper lobe lobectomy with lymph node biopsies.
2. Tumor type:
Squamous cell carcinoma.
3. Histiologic grade:
Moderately differentiated.
4. Tumor size:
2.4 cm
5. Surgical margins:
All surgical margins free of tumor.
6. Direct extension of tumor:
Not identified.
7. Lymphatic (small vessel) invasion:
Absent.
8. Venous (large vessel) invasion:
Absent.
9. Lymph nodes:
Total number of lymph nodes examined: 7
Number of lymph nodes involved 0 (0/7).
10. TNM staging: pT1b, pN0; pMX

MICROSCOPIC EXAMINATION:

[REDACTED]

[page 2 of 3]
- A. Sections are of a benign lymph node with anthracotic pigment. There is no malignancy.
- B. Sections demonstrate fragments of three benign lymph nodes with mild lymphoid hyperplasia and anthracotic pigment. There is no malignancy.
- C. Sections are of a benign lymph node with anthracotic pigment. There is no malignancy.
- D. Multiple sections are examined, and sections of the bronchial surgical margins demonstrate no malignancy. The vascular surgical margins are also free of tumor. There is a peribronchial lymph node with mild anthracotic pigment with no malignancy. Sections of the tumor grossly described demonstrates a neoplasm composed of sheets of somewhat polygonal cells with ill-defined cell borders with small amount of cytoplasm and enlarged hyperchromatic and pleomorphic nuclei with mitotic activity seen. There is focal tumor necrosis. The tumor approaches, but does not involve, the visceral pleura. No lymphovascular invasion is seen. Sections of the adjacent fibrotic area grossly described demonstrates subpleural fibrosis with mild chronic inflammation and focal calcification. No involvement by tumor is seen. Sections of the grossly uninvolved lung demonstrates no significant fibrosis or inflammation.
- E. Sections are of a benign lymph node with lymphoid follicular hyperplasia and anthracotic pigment. There is no malignancy. [REDACTED]

GROSS:

- A. Received in Formalin labeled with the patient's name, account number, and "right upper lobe para bronchial LN" is a single, slightly anthracotic lymph node measuring 0.5 x 0.4 x 0.3 cm in maximum dimensions. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]
- B. Received in Formalin labeled with the patient's name, account number, and "lower right paratracheal LN" is a single fragment of yellow-tan tissue measuring 3 x 1.5 x 1 cm in maximum dimensions. A search is made for potential lymph nodes. A number are found. Representative sections of each potential lymph node are submitted in a single cassette. RS-1 [REDACTED]
- C. Received in Formalin labeled with the patient's name, account number, and "right upper lobe para bronchial LN" is a single, slightly anthracotic lymph node measuring 1.2 x 1 x 0.3 cm in maximum dimensions. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]
- D. Received labeled "right upper lobe" is a 15 x 13 x 8 cm in maximum dimensions lobectomy specimen. There is a mass present on the periphery of the lung with slightly retracted pleura, the latter which is inked in black. The bronchial margin is submitted for frozen section and frozen section diagnosis in block #1. The specimen is then serially sectioned to demonstrate a 2.4 cm in maximum dimensions mass that is seen extending to, but not through, the visceral pleura, the latter which is inked in black. Approximately 2.5 cm adjacent to the tumor is a 3 cm firm area, which on cut surface demonstrates subpleural fibrosis. The remainder of the lung is soft and spongy and mildly anthracotic with no additional masses

[page 3 of 3]
but no definitive tumor. Sections are then submitted for permanent as follows: Cassette #2 - Vascular margins and peribronchial lymph nodes. #3, #4, and #5 - Sections of tumor. #6 - Area of probable subpleural fibrosis. #7 - Random sections of lung. Representative section of the tumor is also submitted for [REDACTED]

- E. Received in Formalin labeled with the patient's name, account number, and "subcarinal lymph node" is a single anthracotic lymph node measuring 3 x 1.5 x 0.5 cm in maximum dimensions. The specimen is bisected and representative sections are submitted in a single cassette. RS-1 [REDACTED]

Electronically Signed by [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 77e92c47-5732-47c7-9c40-7f9ccc6e2dd7 (TCGA-56-8304.7376ADFA-7F9A-4F1D-B878-B3FC105009AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).